Somatic mutation profile of tumor specimen TARGET-15-SJMPAL016342-09A.1 (aliquot TARGET-15-SJMPAL016342-09A.1-01D) from TARGET case TARGET-15-SJMPAL016342, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.9 years (335 days).
Specimen TARGET-15-SJMPAL016342-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad92aba2-ce4e-438b-b260-a48f05ababb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL016342-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL016342-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c2173f0-9d1d-4c0d-a893-a0b66f5b2b8a

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX58 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.4); catalogued as COSV101152776; called by muse, mutect2
- FAR1 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2
- HLA-DQB2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by mutect2, varscan2
- TMEM106B | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2
- UGGT2 | c.1731G>T p.K577N | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.172); called by muse, mutect2
